Somatic mutation profile of tumor specimen TCGA-EK-A2RJ-01A (aliquot TCGA-EK-A2RJ-01A-11D-A18J-09) from TCGA case TCGA-EK-A2RJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 51.1 years (18,664 days).
Specimen TCGA-EK-A2RJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12225ff7-5d19-4afa-a8da-9cf4311b539c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2RJ-10A (Blood Derived Normal), aliquot TCGA-EK-A2RJ-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d392f166-d9df-44af-ba85-fc37c63f5baa

The open-access MAF lists 378 somatic variants for this specimen: 276 protein-altering or splice-affecting, 94 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 248, Silent 94, Nonsense Mutation 24, Splice Site 4, RNA 3, 3'UTR 2, Intron 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.2869C>T p.R957* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs121918440, CM981521, COSV55934187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB7 | c.2202G>C p.K734N (on ENST00000373394 / NM_001271696.3; = p.K735N on NM_004299.6) | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV99504831; called by muse, mutect2, varscan2
- AC134980.2 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs772319712, COSV60909017; called by mutect2, varscan2
- ACP4 | c.979G>C p.D327H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV54518366; called by muse, mutect2, varscan2
- ADAL | c.244G>C p.D82H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as COSV67501314; called by muse, mutect2, varscan2
- ADAM17 | c.282C>G p.F94L | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.074); catalogued as COSV60401518; called by muse, mutect2, varscan2
- ADAM17 | c.13C>T p.L5F | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.02); catalogued as COSV100176532; called by muse, mutect2
- ADCY5 | c.3772C>A p.P1258T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV59203388, COSV59203714; called by mutect2, varscan2
- ADCY8 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53923813, COSV99653606; called by muse, mutect2, varscan2
- ADGRL3 | c.3601G>A p.E1201K (on ENST00000506720 / NM_001322402.2; = p.E1133K on NM_015236.6) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV72231068; called by muse, mutect2, varscan2
- AFDN | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV60041076; called by muse, mutect2, varscan2
- AHNAK2 | c.8571G>C p.K2857N | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as COSV60927983, COSV60928861; called by muse, mutect2
- AL133500.1 | c.1625C>T p.S542L | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious, low confidence (0); catalogued as rs773210279, COSV55744446; called by muse, mutect2, varscan2
- ANKH | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99415882; called by muse, mutect2, varscan2
- ANKLE2 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.085); catalogued as COSV61711277; called by muse, mutect2, varscan2
- ANKRD12 | c.6166G>A p.D2056N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1473791069, COSV50843082; called by muse, mutect2, varscan2
- ANXA2R | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.075); catalogued as COSV59215210; called by muse, mutect2, varscan2
- ATG9A | c.1883C>T p.S628L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1232768462, COSV54699518; called by muse, mutect2, varscan2
- ATP2A2 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV58047075; called by muse, mutect2, varscan2
- ATP2A3 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV59234336; called by muse, mutect2, varscan2
- BABAM2 | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.69); catalogued as COSV59631705; called by muse, mutect2, varscan2
- BBS9 | c.973C>G p.Q325E | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV54184315, COSV99625755; called by muse, mutect2, varscan2
- BCL6 | c.765C>A p.H255Q | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV99216056; called by mutect2, varscan2
- BEND3 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs782423818, COSV64682073; called by muse, mutect2, varscan2
- BIRC2 | c.1762C>G p.H588D | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57162832; called by muse, mutect2, varscan2
- BIRC5 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV56957326; called by muse, mutect2
- BNC2 | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66155565; called by muse, mutect2, varscan2
- BNIP2 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV51108565; called by muse, mutect2, varscan2
- BRD1 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53460898; called by muse, mutect2
- BRWD3 | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64752759; called by muse, mutect2, varscan2
- BST1 | c.423G>C p.L141F | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53946612; called by muse, mutect2, varscan2
- C12orf45 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV55013065, COSV55013439; called by muse, mutect2, varscan2
- C8G | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.665); catalogued as rs753450750, COSV56403041; called by muse, mutect2, varscan2
- CACNA1B | c.4595G>C p.R1532T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53144874; called by muse, mutect2, varscan2
- CACNA1F | c.3341C>T p.S1114L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as CM139716, COSV59906620; called by muse, mutect2, varscan2
- CACNA2D2 | c.2035G>C p.E679Q (on ENST00000479441 / NM_001174051.3; = p.E672Q on NM_006030.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV56568274; called by mutect2, varscan2
- CAPRIN2 | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.376); catalogued as COSV51831146, COSV51835000; called by muse, mutect2, varscan2
- CARD14 | c.1289G>C p.R430P | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.324); catalogued as COSV60124846, COSV60126298; called by muse, mutect2, varscan2
- CCDC12 | c.53G>A p.R18Q (on ENST00000425441 / NM_001277074.1; = p.R31Q on NM_144716.5) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52762355; called by muse, mutect2
- CCDC158 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV66357026; called by muse, mutect2, varscan2
- CCDC27 | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV99622924; called by muse, mutect2
- CCDC81 | c.1671G>C p.M557I (on ENST00000445632 / NM_001156474.2; = p.M467I on NM_021827.4) | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV53581118; called by muse, mutect2, varscan2
- CD40LG | c.99C>G p.I33M | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV65699000; called by muse, mutect2, varscan2
- CDH6 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as COSV54065856; called by muse, mutect2, varscan2
- CDH8 | c.1543C>G p.Q515E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); catalogued as COSV54894760; called by muse, mutect2, varscan2
- CDH9 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1255912071, COSV50389579, COSV50427157; called by muse, mutect2, varscan2
- CDK2 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as rs201353858, COSV57187336; called by muse, mutect2, varscan2
- CDKL2 | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV56735178; called by muse, mutect2, varscan2
- CDX2 | c.616C>T p.H206Y | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV66829859; called by muse, mutect2, varscan2
- CELF5 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV53014652; called by muse, mutect2, varscan2
- CEP350 | c.7062G>C p.K2354N | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as COSV62599001, COSV62608796; called by muse, mutect2
- CEP350 | c.8107G>C p.E2703Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100854298, COSV62608802; called by muse, mutect2, varscan2
- CHD6 | c.6883G>A p.E2295K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV64693825; called by muse, mutect2, varscan2
- CHRM1 | c.377C>A p.S126Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61006978, COSV61007517; called by muse, mutect2, varscan2
- CLASP2 | c.1937C>G p.S646C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.336); catalogued as COSV56292059; called by mutect2, varscan2
- CLEC4C | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV63582972; called by mutect2, varscan2
- COL19A1 | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750042587, COSV100505807, COSV59585071; called by muse, mutect2, varscan2
- COL5A2 | c.1624C>T p.Q542* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV66414179; called by muse, mutect2, varscan2
- CORO1C | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV54598573; called by mutect2, varscan2
- CPSF1 | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as COSV62942132, COSV62943099; called by muse, mutect2, varscan2
- DAZAP1 | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs771366198, COSV51834607, COSV51835890; called by muse, mutect2, varscan2
- DBN1 | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52792464; called by muse, mutect2, varscan2
- DCAF5 | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV58462642; called by muse, mutect2, varscan2
- DDI1 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV56391512; called by muse, mutect2, varscan2
- DENND2C | c.1903G>A p.A635T (on ENST00000393274 / NM_001256404.2; = p.A578T on NM_198459.4) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67923735; called by muse, mutect2, varscan2
- DENND2C | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as rs1187140939, COSV67923743; called by muse, mutect2, varscan2
- DIS3L | c.2861G>C p.R954T (on ENST00000319212 / NM_001143688.3; = p.R871T on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); catalogued as COSV56020880, COSV99972361; called by muse, mutect2
- DLL3 | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs1409127924, COSV52693801; called by muse, mutect2
- DLX4 | c.692C>G p.S231* (on ENST00000240306 / NM_138281.3; = p.S159* on NM_001934.3) | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV53592741; called by muse, mutect2, varscan2
- DMWD | c.687C>G p.F229L | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV52181764; called by muse, mutect2, varscan2
- DNAJC10 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.693); catalogued as rs141135661; called by muse, mutect2, varscan2
- DPAGT1 | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as COSV53829956; called by muse, mutect2, varscan2
- DSG3 | c.2974G>A p.E992K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV57129136; called by muse, mutect2, varscan2
- DST | c.6488G>A p.R2163Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs111657428, COSV55035879; called by muse, mutect2, varscan2
- EARS2 | c.113G>C p.R38P | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54843036, COSV54843089; called by muse, mutect2
- EPHA7 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.272); catalogued as COSV65189973; called by muse, mutect2, varscan2
- EPS8 | c.1499G>C p.R500T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV55535805; called by muse, mutect2, varscan2
- EPS8 | c.924G>C p.R308S | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV55534687, COSV99843690; called by muse, mutect2
- F8 | c.6907C>G p.Q2303E | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as CD123876, CM074161, COSV57706380; called by muse, mutect2, varscan2
- FAM168A | c.411C>G p.I137M (on ENST00000064778 / NM_001286050.2; = p.I128M on NM_015159.3) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.654); catalogued as COSV50359887; called by muse, mutect2, varscan2
- FAM83G | c.932G>C p.S311T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV58761489; called by muse, mutect2, varscan2
- FBXO11 | c.2192G>C p.R731T (on ENST00000403359 / NM_001190274.2; = p.R647T on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV52286307; called by muse, mutect2, varscan2
- FBXO9 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs868352826, COSV55056961; called by muse, mutect2, varscan2
- FLG | c.11099C>T p.S3700L | Missense Mutation (SNP) | VAF 31/276 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV64247435; called by muse, mutect2, varscan2
- FLG | c.401G>C p.R134T | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.351); catalogued as COSV100912211, COSV64251639; called by muse, mutect2
- FMR1 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV54422001, COSV99029106; called by muse, mutect2
- FNIP2 | c.2182G>C p.E728Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52444778; called by mutect2, varscan2
- FOSL2 | c.58C>G p.P20A | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV53105475; called by muse, mutect2
- FRMPD4 | c.3292G>A p.E1098K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.075); catalogued as COSV66221868; called by muse, mutect2, varscan2
- GAB1 | c.1630G>C p.E544Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53760571; called by muse, mutect2, varscan2
- GAD1 | c.752-1G>A p.X251_splice | Splice Site (SNP) | VAF 7/27 reads (26%) | catalogued as COSV60152140; called by muse, mutect2, varscan2
- GALNT11 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753195277, COSV57428210; called by muse, mutect2, varscan2
- GCC2 | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV59179460; called by muse, mutect2
- GDPD4 | c.1067C>G p.S356C | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60022214; called by muse, mutect2, varscan2
- GFRA2 | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60781473; called by muse, mutect2, varscan2
- GGN | c.1893C>G p.I631M | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV53058661; called by muse, mutect2, varscan2
- GLIS1 | c.1650C>G p.F550L | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV56555062; called by muse, mutect2, varscan2
- GOLGA3 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs187961286; called by muse, mutect2, varscan2
- GOLPH3L | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV55047569; called by muse, mutect2, varscan2
- GPN1 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs1434006078, COSV53117271; called by muse, mutect2, varscan2
- GREB1 | c.2241G>C p.Q747H | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.724); catalogued as COSV52194968; called by muse, mutect2, varscan2
- GSK3A | c.1264C>G p.L422V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV55900649; called by muse, mutect2
- GUCY2F | c.407C>G p.S136W | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV54297945, COSV54306707; called by muse, mutect2
- H1-4 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV56803254, COSV56803481; called by muse, mutect2
- H2BC9 | c.69G>C p.Q23H | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs1189676757, COSV55099778, COSV55099825; called by muse, mutect2, varscan2
- H2BC9 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.079); catalogued as COSV55100798; called by muse, mutect2, varscan2
- HABP4 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1419089710, COSV64515104, COSV64515257; called by muse, mutect2, varscan2
- HCRTR2 | c.826C>G p.R276G | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as rs1562031479, COSV63798648; called by muse, mutect2, varscan2
- HFM1 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.098); catalogued as COSV54035741; called by muse, mutect2, varscan2
- HIPK2 | c.3464C>T p.S1155L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs752555598, COSV69208078, COSV69209334; called by muse, mutect2, varscan2
- HMSD | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as COSV68817067; called by muse, mutect2, varscan2
- IARS2 | c.674G>C p.R225T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.396); catalogued as COSV56963480; called by muse, mutect2, varscan2
- IL12A | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59760005; called by muse, mutect2
- IL3RA | c.35C>A p.A12D | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV100452394; called by muse, mutect2
- IL3RA | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 11/139 reads (8%) | catalogued as rs1407012338, COSV100452395; called by muse, mutect2
- INPPL1 | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV53358834; called by muse, mutect2, varscan2
- INTS8 | c.2579G>A p.G860E | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58252937; called by muse, mutect2, varscan2
- ITPR3 | c.6405G>C p.Q2135H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753304008, COSV65414219; called by mutect2, varscan2
- KAT5 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1364365744, COSV57730163; called by muse, mutect2, varscan2
- KCNA5 | c.1649G>C p.R550T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV52908187; called by muse, mutect2
- KDM4C | c.3140C>G p.S1047C | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); catalogued as COSV67191332; called by muse, mutect2
- KDM5C | c.3826G>A p.E1276K | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64763185; called by muse, mutect2
- KIAA1549 | c.5591G>C p.R1864T | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54325721; called by muse, mutect2, varscan2
- KRTAP10-9 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV59977081; called by muse, mutect2, varscan2
- LAS1L | c.688C>G p.Q230E | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100408689; called by muse, mutect2
- LATS2 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66879123; called by muse, mutect2, varscan2
- LCE3C | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV61610203, COSV61610290; called by muse, mutect2, varscan2
- LGALS8 | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV53026145; called by muse, mutect2, varscan2
- LILRB3 | c.1891C>G p.P631A (on ENST00000346401; = p.P619A on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as rs1324581888, COSV99558472; called by muse, mutect2
- LPIN1 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1216089720, COSV56769947; called by muse, mutect2
- LPL | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.673); catalogued as COSV60932625; called by muse, mutect2, varscan2
- LRRC66 | c.1703C>G p.S568* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV58634350; called by mutect2, varscan2
- LRRFIP1 | c.1574C>G p.S525C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV57832572; called by muse, mutect2, varscan2
- MAGEB3 | c.858G>A p.M286I | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV64397667; called by muse, mutect2, varscan2
- MAGEC3 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs369863174, COSV71610185; called by muse, mutect2, varscan2
- MAGI2 | c.2599G>C p.E867Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as COSV62683805, COSV62684832; called by muse, mutect2, varscan2
- MAP4 | c.2122C>G p.Q708E | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV99276273; called by muse, mutect2
- MARF1 | c.3666G>C p.L1222F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV60028166; called by muse, mutect2, varscan2
- MAST1 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.688); catalogued as rs1027549820, COSV52253876; called by muse, mutect2, varscan2
- MCF2 | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 10/83 reads (12%) | catalogued as COSV58493663; called by muse, mutect2, varscan2
- MDN1 | c.13252G>C p.D4418H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV65528928; called by muse, mutect2, varscan2
- MEOX1 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs750330652, COSV59357241; called by mutect2, varscan2
- MGAT5 | c.356C>G p.S119C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.176); catalogued as COSV99925111; called by muse, mutect2, varscan2
- MICU3 | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV58848433, COSV58849526; called by muse, mutect2, varscan2
- MLPH | c.147G>C p.K49N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs767964025, COSV52823481; called by muse, mutect2, varscan2
- MOAP1 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV52093352; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1921C>G p.Q641E | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV100187226; called by muse, mutect2, varscan2
- MRPL9 | c.435+1G>A p.X145_splice | Splice Site (SNP) | VAF 41/51 reads (80%) | catalogued as COSV58617478; called by muse, mutect2, varscan2
- MSANTD2 | c.1600G>A p.E534K (on ENST00000374979 / NM_001308027.2; = p.E482K on NM_024631.4) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV53450915, COSV99515615; called by muse, varscan2
- MTHFD1L | c.1955G>A p.G652D | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66227092; called by muse, mutect2, varscan2
- MTUS2 | c.3604C>T p.Q1202* (on ENST00000612955 / NM_001366650.1; = p.Q181* on NM_015233.6) | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV66422944; called by muse, mutect2, varscan2
- NBEA | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as COSV59816244; called by muse, mutect2, varscan2
- NBEA | c.4654C>T p.R1552W | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1383053577, COSV59816267; called by muse, mutect2, varscan2
- NBEAL1 | c.5314C>G p.L1772V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV71374367, COSV71375360; called by muse, mutect2, varscan2
- NDUFS1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.964); catalogued as COSV51913121; called by muse, mutect2, varscan2
- NECTIN2 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs138153191; called by muse, mutect2, varscan2
- NEK4 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51782891; called by muse, mutect2, varscan2
- NLK | c.481G>T p.G161* | Nonsense Mutation (SNP) | VAF 5/64 reads (8%) | catalogued as COSV101311367; called by muse, mutect2
- NLRC3 | c.2770G>A p.D924N | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.987); catalogued as COSV57095083; called by muse, mutect2
- NUP85 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55466168, COSV55466396; called by muse, mutect2, varscan2
- OAZ1 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV100457495; called by muse, mutect2, varscan2
- OAZ1 | c.423C>G p.I141M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs772512082, COSV59233621; called by muse, mutect2, varscan2
- OGT | c.2861G>C p.R954P | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101035579, COSV65481013, COSV65482385; called by muse, mutect2, varscan2
- OPN1SW | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs373496991; called by muse, mutect2, varscan2
- OR1J2 | c.276C>G p.I92M | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.373); catalogued as COSV58944321, COSV58945019; called by muse, mutect2, varscan2
- P2RX2 | c.193A>T p.K65* (on ENST00000343948 / NM_170683.4; = p.E42V on NM_012226.5) | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV57688817; called by muse, mutect2, varscan2
- P3H2 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as COSV60026997; called by muse, mutect2, varscan2
- PARP14 | c.1393C>T p.Q465* | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | catalogued as COSV101506285, COSV71735461; called by muse, mutect2
- PCDHA3 | c.2387C>T p.S796L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.001); catalogued as COSV63545209; called by muse, mutect2, varscan2
- PCF11 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as COSV53529856, COSV53531621; called by muse, mutect2, varscan2
- PCIF1 | c.699C>G p.F233L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65027109; called by mutect2, varscan2
- PCYOX1L | c.745G>T p.V249F | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51004802; called by muse, mutect2, varscan2
- PDP1 | c.1098G>C p.K366N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.043); catalogued as COSV52603625; called by muse, mutect2, varscan2
- PHF8 | c.1363G>A p.E455K (on ENST00000357988 / NM_001184896.1; = p.E419K on NM_015107.3) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV57686538; called by muse, mutect2, varscan2
- PIK3R3 | c.116C>G p.P39R | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs780117361, COSV53110679; called by muse, mutect2, varscan2
- PLA2G4F | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.972); catalogued as COSV51829136; called by muse, mutect2, varscan2
- PLEKHM3 | c.1528C>G p.Q510E | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101216879; called by muse, mutect2, varscan2
- PLEKHO1 | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV50311204; called by muse, mutect2, varscan2
- PLXNB1 | c.2081C>G p.P694R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as COSV56493614; called by muse, mutect2, varscan2
- PRDM2 | c.4083G>C p.K1361N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV52454322; called by muse, mutect2, varscan2
- PRODH2 | c.1005G>A p.W335* (on ENST00000301175; = p.W259* on NM_021232.2 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/104 reads (8%) | catalogued as COSV56561698; called by muse, mutect2
- PSG11 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.285); catalogued as rs375462400; called by muse, mutect2, varscan2
- PSG6 | c.327G>C p.Q109H | Missense Mutation (SNP) | VAF 18/417 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV51833308; called by muse, mutect2
- PTBP3 | c.812G>C p.R271T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV57586756; called by muse, mutect2, varscan2
- PTCHD4 | c.2355C>G p.F785L | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV59795244; called by muse, mutect2
- PTPRC | c.1865-1G>C p.X622_splice | Splice Site (SNP) | VAF 7/41 reads (17%) | catalogued as COSV61419695; called by muse, mutect2, varscan2
- PYGB | c.1121C>G p.A374G | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.521); catalogued as rs540251614, COSV53822281; called by muse, mutect2, varscan2
- RAB6A | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as COSV60179948; called by muse, mutect2, varscan2
- RABL3 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV99382166, COSV99382169; called by muse, mutect2
- RASIP1 | c.1840A>T p.I614F | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV55807837; called by muse, mutect2, varscan2
- RBM42 | c.1274G>A p.G425D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV52898957; called by muse, mutect2, varscan2
- RBP5 | c.253-1G>C p.X85_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | catalogued as COSV56952651; called by muse, mutect2, varscan2
- RECQL5 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as COSV100512395, COSV58645599; called by muse, mutect2, varscan2
- REST | c.2395C>G p.P799A | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.054); catalogued as COSV58362435; called by muse, mutect2, varscan2
- RHCG | c.1359C>A p.F453L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV51518174; called by muse, mutect2, varscan2
- ROCK2 | c.2186A>G p.K729R | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs749156202, COSV99837881; called by muse, mutect2, varscan2
- RRAGA | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0.017); catalogued as COSV100998176; called by muse, mutect2
- RYR2 | c.4343C>T p.S1448L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV63709244; called by mutect2, varscan2
- RYR3 | c.7037C>A p.S2346* (on ENST00000389232; = p.S2347* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV66805919; called by mutect2, varscan2
- S100A7A | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); catalogued as COSV61331195; called by muse, mutect2, varscan2
- SARAF | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as COSV56358197; called by muse, mutect2, varscan2
- SBF2 | c.2995C>T p.Q999* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as rs770281252, COSV56308969; called by muse, mutect2, varscan2
- SBNO2 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV100685024; called by muse, mutect2, varscan2
- SCN1B | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.264); catalogued as COSV52885694; called by muse, mutect2, varscan2
- SEC16A | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.254); catalogued as COSV51538883; called by muse, mutect2, varscan2
- SEC63 | c.1732G>C p.E578Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV64601764; called by muse, mutect2, varscan2
- SELENOK | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as COSV59832827; called by muse, mutect2, varscan2
- SEMA6C | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59006567, COSV59007051, COSV59007588; called by muse, mutect2, varscan2
- SENP2 | c.799C>G p.Q267E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.036); catalogued as COSV56197288; called by muse, mutect2, varscan2
- SLC10A3 | c.1196T>C p.V399A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV54837258; called by muse, mutect2
- SLC14A2 | c.1224C>G p.I408M | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.422); catalogued as COSV54913866; called by muse, mutect2, varscan2
- SLC16A13 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV100338760; called by muse, mutect2
- SLC25A6 | c.273C>G p.F91L | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV101195512; called by muse, mutect2
- SLC26A3 | c.557C>G p.S186C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.401); catalogued as COSV60642258; called by mutect2, varscan2
- SLC26A3 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV60642266; called by muse, mutect2, varscan2
- SLIT3 | c.3949G>A p.D1317N | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV60630246; called by muse, mutect2
- SMAD3 | c.384G>C p.Q128H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); catalogued as COSV59288861; called by muse, mutect2, varscan2
- SMARCB1 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV53157696; called by muse, mutect2, varscan2
- SMC1A | c.2191C>G p.L731V | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.049); catalogued as COSV100447680; called by muse, mutect2, varscan2
- SMOC2 | c.949C>G p.L317V (on ENST00000356284 / NM_001166412.2; = p.L328V on NM_022138.3) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.705); catalogued as COSV62443120; called by muse, mutect2, varscan2
- SNCAIP | c.2408C>T p.S803F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54419776; called by muse, mutect2, varscan2
- SNX1 | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV56039803; called by muse, mutect2, varscan2
- SOX15 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.01); catalogued as COSV51468183, COSV51469412; called by muse, mutect2, varscan2
- SPEF2 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as COSV56794915, COSV56795332; called by muse, mutect2
- SPTBN1 | c.3784G>C p.E1262Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV61693099; called by muse, mutect2, varscan2
- STRC | c.3652C>G p.Q1218E | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.099); catalogued as COSV101372243; called by muse, mutect2, varscan2
- STRN4 | c.2021C>G p.S674C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54420687; called by mutect2, varscan2
- STRN4 | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99624057; called by muse, mutect2, varscan2
- STX11 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.643); catalogued as COSV62450208; called by muse, mutect2, varscan2
- SUPV3L1 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV62846197; called by muse, mutect2, varscan2
- SYNE1 | c.17804C>A p.A5935D (on ENST00000367255 / NM_182961.4; = p.A5864D on NM_033071.3) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55079881; called by muse, mutect2
- SYNE3 | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV62082079; called by muse, mutect2, varscan2
- SYT10 | c.305G>C p.S102T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV57344622; called by muse, mutect2, varscan2
- TCHH | c.4865G>A p.R1622H | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as COSV100914884, COSV64275588; called by muse, mutect2
- TCL1B | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.449); catalogued as COSV61552307, COSV61552453; called by muse, mutect2, varscan2
- THSD7A | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as rs866976180, COSV70271129; called by mutect2, varscan2
- THYN1 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as rs202070344, COSV55542331; called by muse, mutect2, varscan2
- TJP1 | c.2633C>T p.S878F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62045816; called by muse, mutect2, varscan2
- TLK1 | c.2191G>T p.D731Y | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62632636; called by muse, mutect2, varscan2
- TMEM108 | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.01); catalogued as COSV58881207; called by muse, mutect2, varscan2
- TMEM150A | c.148G>A p.E50K (on ENST00000334462 / NM_001031738.3; = p.L19= on NM_153342.3) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV57818545; called by muse, mutect2, varscan2
- TMEM165 | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.089); catalogued as COSV63529269; called by muse, mutect2, varscan2
- TMEM38B | c.611C>G p.S204* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV101016215, COSV65949632; called by muse, mutect2, varscan2
- TMEM61 | c.69C>A p.S23R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV64873819, COSV64873868; called by muse, mutect2, varscan2
- TNRC18 | c.4709C>T p.A1570V | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs757870927, COSV68169678; called by muse, mutect2, varscan2
- TPBG | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV63883038; called by muse, mutect2, varscan2
- TRAPPC9 | c.1513C>T p.Q505* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV66908457; called by muse, mutect2, varscan2
- TRIM41 | c.888G>C p.E296D | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.628); catalogued as COSV59322038; called by muse, mutect2, varscan2
- TRPM4 | c.1763C>T p.S588L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV53261424; called by muse, mutect2, varscan2
- TSC22D1 | c.1669C>T p.Q557* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV71775051, COSV71776216; called by muse, mutect2, varscan2
- TTC30A | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV63102265; called by muse, mutect2
- TTI1 | c.2764G>A p.A922T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs200742197, COSV65063115; called by muse, mutect2, varscan2
- TUBGCP6 | c.2996C>T p.S999L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs767848372, COSV50575631; called by muse, mutect2, varscan2
- UBR5 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55297801; called by muse, mutect2, varscan2
- URGCP | c.1606C>G p.R536G (on ENST00000453200 / NM_001077663.3; = p.R527G on NM_017920.4) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56245603, COSV56251886; called by muse, mutect2, varscan2
- USH2A | c.10663G>T p.E3555* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV56423761, COSV56424033; called by muse, mutect2, varscan2
- USP20 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs751125529, COSV59618269; called by muse, mutect2, varscan2
- USP4 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55540095; called by muse, mutect2, varscan2
- USP7 | c.1174G>A p.G392S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61215684, COSV61216460; called by muse, varscan2
- VASP | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV55608013; called by muse, mutect2, varscan2
- WSCD1 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58497767; called by muse, mutect2
- XCR1 | c.24G>C p.E8D | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV58570510; called by muse, mutect2, varscan2
- XPO7 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.532); catalogued as COSV53019372; called by mutect2, varscan2
- ZC3H13 | c.4379G>A p.G1460E (on ENST00000242848 / NM_001330565.2; = p.G1461E on NM_015070.6) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.031); catalogued as COSV54461806; called by muse, mutect2, varscan2
- ZMYND8 | c.409G>C p.E137Q (on ENST00000311275 / NM_001363741.2; = p.E157Q on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53695193, COSV53695279; called by muse, mutect2, varscan2
- ZNF217 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.536); catalogued as COSV56601464; called by muse, mutect2, varscan2
- ZNF391 | c.774C>A p.F258L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV55124545, COSV55125533; called by muse, mutect2, varscan2
- ZNF582 | c.810G>C p.L270F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV56733517; called by muse, mutect2, varscan2
- ZNF620 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs199758819; called by muse, mutect2, varscan2
- ZNF708 | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV63608615; called by muse, mutect2, varscan2
- ZNF768 | c.96G>A p.M32I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV53224696; called by muse, mutect2, varscan2
- ZNF768 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs775095059, COSV53223857, COSV99411346; called by muse, mutect2, varscan2
- ZNF778 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as COSV60602639; called by muse, mutect2, varscan2
- ZNF836 | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.154); catalogued as COSV59086040; called by muse, mutect2, varscan2
- MLF2 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.018); called by muse, mutect2
- TGM2 | c.1092G>C p.K364N | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- ACOT13 | c.422G>A p.*141= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs555358026, COSV57765594; called by muse, mutect2
- AL133500.1 | c.1191G>A p.S397= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs768053440, COSV99860342, COSV99860486; called by muse, mutect2, varscan2
- ALAS1 | c.1092C>A p.L364= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as COSV100050486; called by muse, mutect2
- AP4B1 | c.547C>T p.L183= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs1008492819, COSV56726703, COSV99871191; called by muse, mutect2, varscan2
- ARRDC1 | c.768C>T p.S256= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV58380631; called by muse, mutect2, varscan2
- ATP2A3 | c.2361G>A p.L787= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV59234357; called by muse, mutect2, varscan2
- BEND2 | c.2136G>A p.L712= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV66217017; called by muse, mutect2, varscan2
- BRWD3 | c.3564C>T p.L1188= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV64752748; called by muse, mutect2, varscan2
- BUB1B | c.747C>T p.L249= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV99807314; called by muse, mutect2
- CAMK2B | c.1845C>T p.A615= | Silent (SNP) | VAF 11/136 reads (8%) | catalogued as COSV51661124, COSV99323544; called by muse, mutect2
- CDHR1 | c.1200G>A p.V400= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV60565893; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1515C>A p.I505= (on ENST00000357886 / NM_001365728.1; = p.I491= on NM_016082.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV100212304; called by muse, mutect2, varscan2
- CEACAM4 | c.336C>T p.I112= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as rs781899276, COSV55732664; called by muse, mutect2
- CELA2A | c.393C>T p.V131= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV62747987; called by muse, mutect2, varscan2
- CGN | c.204C>G p.L68= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV54972977; called by muse, mutect2, varscan2
- CHL1 | c.258G>A p.S86= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs780080487, COSV56585572; called by muse, mutect2, varscan2
- CIP2A | c.1764G>A p.L588= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV55420960; called by muse, mutect2, varscan2
- CS | c.30C>G p.L10= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV60834630; called by muse, mutect2, varscan2
- DAAM2 | c.444C>T p.F148= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV99227088; called by muse, mutect2
- DMWD | c.933C>T p.F311= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs1379422230, COSV52181758; called by muse, mutect2, varscan2
- DNAH5 | c.6303C>T p.F2101= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV54243898; called by muse, mutect2
- EIF3K | c.213G>T p.L71= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV50264276, COSV50264498; called by muse, mutect2, varscan2
- ELMOD3 | c.540G>A p.K180= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV59775326; called by muse, mutect2, varscan2
- EMD | c.486G>A p.Q162= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs781879653, COSV63962441; called by muse, mutect2, varscan2
- EXTL3 | c.1356C>T p.F452= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs200003224, COSV55040135; called by muse, mutect2, varscan2
- FAM227B | c.699G>A p.V233= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV54817953; called by muse, mutect2, varscan2
- FLNA | c.63C>G p.V21= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV61050019; called by muse, mutect2, varscan2
- FNDC3B | c.585G>A p.L195= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV61048326; called by muse, mutect2, varscan2
- FRG2 | c.372A>G p.K124= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- GPR42 | c.873G>A p.L291= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV71995086; called by muse, mutect2, varscan2
- GUCY1B1 | c.450C>T p.I150= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV52378473; called by mutect2, varscan2
- HLA-DQA1 | c.369G>A p.V123= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV58241618; called by mutect2, varscan2
- HSF5 | c.213C>T p.L71= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV60203011; called by muse, mutect2, varscan2
- IL3RA | c.357C>T p.F119= | Silent (SNP) | VAF 11/156 reads (7%) | catalogued as COSV100452291, COSV58430186, COSV58433468; called by muse, mutect2
- JAML | c.381C>T p.F127= (on ENST00000356289 / NM_001098526.2; = p.F117= on NM_153206.3) | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs896941133, COSV52629264; called by muse, mutect2, varscan2
- KANK3 | c.1914C>T p.I638= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs371284725; called by muse, mutect2, varscan2
- KCNV2 | c.453C>T p.F151= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs758516182, COSV66057335; called by muse, mutect2, varscan2
- KIAA1217 | c.1251C>T p.V417= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100287313; called by muse, mutect2, varscan2
- KLHL42 | c.1383G>A p.S461= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV67146166; called by muse, mutect2, varscan2
- KRT34 | c.282C>T p.F94= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as COSV67450561; called by muse, mutect2, varscan2
- MAN2C1 | c.2724G>A p.L908= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV51239934; called by muse, mutect2
- MCM5 | c.642C>T p.I214= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as COSV53347964; called by muse, mutect2, varscan2
- MCMDC2 | c.957C>T p.Y319= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV58040271; called by muse, mutect2, varscan2
- MED23 | c.2673C>G p.L891= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV63436562; called by muse, mutect2, varscan2
- MEN1 | c.432C>T p.F144= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as CX055790, COSV56343905; called by muse, mutect2
- MRPL2 | c.28C>T p.L10= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV52438882; called by muse, mutect2, varscan2
- NAALAD2 | c.318C>T p.L106= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as COSV100428827; called by muse, mutect2
- NKX2-2 | c.627C>G p.V209= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs754196742, COSV65820263; called by muse, mutect2, varscan2
- NT5C | c.456G>A p.Q152= | Silent (SNP) | VAF 22/158 reads (14%) | catalogued as COSV55461953; called by muse, mutect2, varscan2
- OARD1 | c.141C>G p.L47= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1463584251, COSV99770376; called by mutect2, varscan2
- OGFOD1 | c.498C>T p.F166= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV60201350; called by muse, mutect2
- PCYT1B | c.1074C>T p.I358= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV100770856; called by muse, mutect2
- PFAS | c.2808C>T p.V936= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs751640861, COSV100119147; called by muse, varscan2
- PLEC | c.7707G>A p.Q2569= (on ENST00000322810 / NM_201380.4; = p.Q2459= on NM_000445.5) | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV59686826; called by muse, mutect2, varscan2
- PLIN3 | c.363C>A p.T121= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99701726; called by muse, mutect2, varscan2
- PPP1R3F | c.2148C>G p.L716= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs138904738, COSV50017874, COSV50020037; called by muse, mutect2, varscan2
- PRCP | c.333G>A p.E111= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV57291297; called by muse, mutect2, varscan2
- PRDM9 | c.1017C>T p.I339= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV57012040; called by muse, mutect2, varscan2
- PRPF6 | c.1740C>T p.A580= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs748133786, COSV53877454, COSV99412118; called by muse, mutect2, varscan2
- PTGDR2 | c.309C>T p.F103= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs1236588022, COSV57126221, COSV99920117; called by muse, mutect2, varscan2
- RAVER1 | c.1179C>T p.P393= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1052503500, COSV53345721; called by muse, mutect2
- RIMS1 | c.3339G>A p.R1113= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs1222041993, COSV53444068; called by muse, mutect2
- RPS16 | c.426G>A p.Q142= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV52239870; called by muse, mutect2, varscan2
- SAMD3 | c.432G>A p.T144= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs377087757, COSV60774290; called by muse, mutect2
- SEMA3A | c.2315G>A p.*772= | Silent (SNP) | VAF 19/155 reads (12%) | catalogued as rs200245362; called by muse, mutect2, varscan2
- SERPINA10 | c.930C>T p.L310= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs771241638; called by muse, mutect2
- SEZ6L2 | c.6G>A p.G2= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs149205260; called by muse, mutect2, varscan2
- SLC6A3 | c.1416C>T p.F472= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV54368791; called by muse, mutect2, varscan2
- SORL1 | c.1269C>G p.V423= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV52761274; called by muse, mutect2
- SOX6 | c.915A>G p.V305= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs778593289, COSV57055848; called by muse, mutect2, varscan2
- SPATA31D1 | c.2085C>T p.L695= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs772371244, COSV61200325; called by muse, mutect2, varscan2
- STRN4 | c.2217C>T p.L739= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV52184562, COSV99354649; called by muse, mutect2, varscan2
- THRAP3 | c.2151C>T p.L717= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs1401856682, COSV63569519; called by muse, mutect2, varscan2
- TMEM92 | c.99C>G p.A33= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV55946843; called by muse, mutect2, varscan2
- TNF | c.357G>A p.L119= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV69305278; called by muse, mutect2, varscan2
- TNR | c.2760C>T p.I920= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as COSV99691575; called by muse, mutect2
- TNS2 | c.924C>G p.L308= (on ENST00000314250 / NM_170754.4; = p.L318= on NM_015319.2) | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV58581387; called by muse, mutect2, varscan2
- TSNAXIP1 | c.177C>G p.L59= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV66315442, COSV66315530; called by muse, mutect2, varscan2
- UBE3C | c.2730T>A p.P910= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV61955331; called by muse, mutect2, varscan2
- UHRF1 | c.213C>A p.L71= (on ENST00000612630 / NM_001290050.1; = p.L84= on NM_013282.4) | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV53575768; called by muse, mutect2, varscan2
- VEZT | c.1131G>A p.V377= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV54144341; called by muse, mutect2, varscan2
- WDR72 | c.840C>T p.I280= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV64752796; called by muse, mutect2, varscan2
- WDR81 | c.4020G>A p.A1340= (on ENST00000409644 / NM_001163809.2; = p.A289= on NM_152348.4) | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs377573673; called by muse, mutect2
- XPNPEP3 | c.1122C>G p.L374= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs761504767, COSV63210170, COSV63210201; called by muse, mutect2, varscan2
- ZBTB22 | c.612C>T p.S204= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV56472230; called by muse, mutect2, varscan2
- ZFP36L1 | c.15C>T p.L5= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV60546675, COSV60546942; called by muse, mutect2, varscan2
- ZGRF1 | c.6219G>C p.L2073= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV71393721; called by muse, mutect2, varscan2
- ZMYM3 | c.186C>A p.T62= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs765997122, COSV58740351; called by muse, mutect2, varscan2
- ZNF254 | c.168C>T p.V56= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV60055138; called by muse, mutect2, varscan2
- ZNF468 | c.858C>G p.L286= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV54696618, COSV99700630; called by muse, mutect2, varscan2
- ZNF552 | c.90C>T p.L30= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as COSV101197563; called by muse, mutect2, varscan2
- ZNF618 | c.2838C>T p.L946= (on ENST00000374126 / NM_001318042.2; = p.L853= on NM_133374.2) | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1564354032, COSV55923236; called by muse, mutect2, varscan2
- ZNF791 | c.1647G>A p.E549= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV58482479; called by muse, mutect2, varscan2
- ZSWIM2 | c.1182T>G p.T394= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV54578900; called by muse, mutect2, varscan2
- AC024940.1 | n.2328G>A | RNA (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504399 G>A | 5'Flank (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- C9orf64 | c.-2G>A | 5'UTR (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100123650; called by muse, mutect2, varscan2
- FAM174C | c.*154G>A | 3'UTR (SNP) | VAF 16/75 reads (21%) | catalogued as COSV69703200; called by muse, mutect2, varscan2
- HERC2P3 | n.742G>A | RNA (SNP) | VAF 28/203 reads (14%) | catalogued as rs540674068; called by muse, mutect2, varscan2
- PDE4B | c.477-153C>T | Intron (SNP) | VAF 10/52 reads (19%) | catalogued as rs770071189, COSV58492459; called by muse, mutect2, varscan2
- SMIM29 | c.*229C>T | 3'UTR (SNP) | VAF 4/22 reads (18%) | catalogued as COSV58988863; called by muse, mutect2
- SNORD114-22 | n.64G>A | RNA (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
